Surgical pathology report (de-identified scan), TCGA case TCGA-09-2044, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2044-01B (Primary Tumor).

[page 1 of 6]
A: Right tube and ovary (FS)

A: Right tube and ovary (FS)

B: Uterus and left tube and ovary (fresh)

C: Sigmoid implant

D: Cul de sac Nodule

E: Right Common Iliac, biopsy

F: Right pelvic Lymph node

G: Left pelvic Lymph node

H: Pelvic Peritoneum, biopsy

I: Bladder, biopsy

J: Left pelvic biopsy

K: Right abdominal biopsy

L: Left abdominal side wall biopsy

M: Omentum, resection other than for tumor

Final Pathologic Diagnosis:

Page 1 of 6

- Myometrium: No significant pathologic abnormality.

[page 2 of 6]
- Endometrium: Atrophic.
- Cervix: Metastatic serous transitional cell carcinoma on the posterior serosal surface; see comment.
- Ovary: No significant pathologic abnormality.
- Fallopian tube: No significant pathologic abnormality.
- C. Soft tissue, "sigmoid implant," biopsy: Metastatic serous transitional cell carcinoma, 1.3 cm.
- D. Soft tissue, "cul-de-sac nodule," excision: Metastatic serous transitional cell carcinoma, 3.5 cm; see comment.
- E. Lymph nodes, right common iliac, dissection: No carcinoma identified in two lymph nodes (0/2).
- F. Lymph nodes, right pelvic, dissection: No carcinoma identified in nine lymph nodes (0/9)
- G. Lymph nodes, left pelvic, dissection: No carcinoma in ten lymph nodes (0/10).
- H. Soft tissue, "pelvic peritoneum," biopsy: Vascular fibroadipose tissue, no tumor identified.
- I. Urinary bladder, biopsy: Vascular fibromuscular and adipose tissue, no tumor identified.
- J. Soft tissue, "left pelvic," biopsy: Vascular fibroadipose tissue, no tumor identified.
- K. Soft tissue, "right abdominal," biopsy: Fibromuscular tissue, no tumor identified.
- L. Soft tissue, "left abdominal sidewall," biopsy: Fibroadipose tissue, no tumor identified.
- M. Omentum, resection: Adipose tissue, no tumor identified.

Note: Ovarian Tumor Synoptic Comment

- **Location of tumor:** Unilateral, right ovary..
- **Type of tumor:** Serous transitional cell carcinoma. Transitional cell carcinoma of the ovary is a morphologic diagnosis. This tumor type is thought to be a variant of serous carcinoma with a similar behavior.
- **Grade of tumor:** High grade.
- **Size of tumor:** 13.3 cm.
- **Surface of ovary:** Tumor on surface.

Page 2 of 6

- **Condition of capsule:** Received in Pathology as ruptured; however, the operation report indicated that the tumor ruptured after removal from the abdomen.
- **Cut surface:** Solid and cystic, mainly cystic.
- **Necrosis:** Focal.
- **Lymphatic/vascular invasion:** None.
- **Sites of metastases in pelvis:** Uterine serosa and cul-de-sac peritoneum.
- Size of largest pelvic metastasis is 5.7 cm.
- **Pelvic lymph nodes:** Negative.
- Total number of nodes examined: 21.
- **Sites of metastases in abdomen:** Serosa of bowel (part C labeled as "sigmoid implant").
- **Size of largest abdominal metastasis:** 1.3 cm.
- **Para-aortic lymph nodes:** None present.
- **Peritoneal cytology:** Cytology CoPath accession number: [REDACTED] negative.
- **Other findings:** None.
- **FIGO stage:** IIB.
- **AJCC stage:** pT2bN0MX.

In Part C, an immunohistochemical stain for keratin is performed and evaluated on block C1 to confirm

[page 3 of 6]
the diagnosis. The keratin stain shows positive staining, thus establishing the diagnosis of metastatic serous transitional cell carcinoma in the "sigmoid implant."

Intraoperative Consult Diagnosis

FS1 (A) Right tube and ovary, salpingo-oophorectomy: Poorly differentiated carcinoma.

Clinical History

The patient is a [REDACTED] with a right ovarian mass who undergoes resection of the mass with a total abdominal hysterectomy, bilateral salpingo-oophorectomy, and staging procedure. Per electronic medical record (STOR), the operation report states that the cystic right ovarian mass ruptured after removal from the abdomen.

Gross Description

The specimen is received in thirteen parts, each labeled with the patient's name and medical record number. Parts A and B are received fresh, while Parts C-M are received in formalin.

Part A is additionally labeled "right tube and ovary" and consists of a disrupted and deflated cystic mass. Within the cyst there are two solid areas composed of soft friable papillary white-pink tissue. Solid area #1 is located at the superior aspect, adjacent to the fallopian tube, and measures 6.5 x 5.5 x 1.3 cm. The site of rupture is located adjacent to solid area #1, beneath the isthmus of the fallopian tube. Solid area #2 is located on the inferior aspect of the cyst and measures 7 x 5.2 x 4.4 cm. The external surface to solid area #2 is rough with small tan-pink excrescences. A portion of the solid area is submitted for frozen section diagnosis #1 with the frozen remnant submitted in cassette A1. A portion of the specimen is tumor banked for research. The cystic mass measures 13.3 x 8 x 4.4 cm and contains apparent white-gold remnant of ovarian parenchyma adjacent to a cystic space containing similar tan-white friable papillary tissue adjacent to solid area #1.

The apparent fallopian tube measures 6.4 cm in length with an average diameter of 0.6 cm. One end consists of fragmented rough tissue and the inferior aspect is adhered to the cystic mass. On cross sections, there are numerous tan-white round lumens that appears to be blood vessels.

The entire specimen weighs 182 gm. The outer surface of the cystic mass is inked in black and the outer surface of the area of disruption is inked in blue for microscopic evaluation. Representative sections are submitted as follows:

Cassette A2: Solid area #1.

Cassettes A3-A6: Solid area #1.

Cassette A7: Solid area #1 at site of disruption.

Cassettes A8-A10: Solid area #2, one section.

Page 3 of 6

Cassettes A11-12: Solid area #2, two section.

Cassettes A13: Solid area #2, one section.

Cassettes A14-A15: Apparent fallopian tube, fimbria bisected and entirely submitted.

Cassette A16: Apparent fallopian tube, cross sections.

Cassette A17: Solid area #1.

After evaluating the slides from the above sections, additional sections are submitted to identify fallopian tube. No apparent fallopian tube is identified. A cystic structure on the surface of the mass is submitted for microscopic evaluation.

Cassettes A18-A21: Cystic structure on the surface of the mass.

Part B is additionally labeled "2 uterus & left tube + ovary" and consists of a uterus with a mass on the lateral left serosal surface beneath the fallopian tube and ovary, extending to the posterior lower uterine and cervical outer surface. This mass is encapsulated by a smooth thin white-pink capsule that appears to be disrupted at the posterior surface. On cut sections, the mass consists of friable papillary fronds of soft tissue that is beneath the serosal surface with a maximum of 0.3 cm extension into the myometrium. The mass does not extend to the endometrium or the uterine cavity. This mass measures 5.7 from superior to inferior, 5.3 from medical to lateral, and 2.2 cm from anterior to posterior. The mass does not involve the ovary or fallopian tube.

[page 4 of 6]
The specimen was received opened along the right lateral border prior to receipt in Pathology. The uterus measures 6.6 cm from superior to inferior, 4.3 cm from cornu to cornu, and 2.8 cm from cornu to cornu. The uterus sounds to 5.7 cm. The myometrium measures 1.4 cm in thickness and the endometrium is tan, with a thickness of 0.1 cm. The cervix measures 2.2 cm in length and 1.4 cm in width. The cervical os is fish-mouth and has a diameter of 0.9 cm. The uterus is oriented by the presence of the left adnexa. The fallopian tube measures 6.5 cm in length and 0.5 cm in average diameter. The fimbria is lush and contains no mass or cysts. The ovary is firm white-tan consists of homogenous white-pink parenchyma containing no mass or lesion. The ovary measures 1.8 x 0.9 x 0.6 cm. The entire specimen weighs 98.7 gm. The specimen is inked as follows for microscopic evaluation: the anterior uterine surface in blue, the posterior uterine surface in black, and the outer surface of the mass in green. The entire fallopian tube is submitted for microscopic evaluation. Representative sections are submitted as follows:

Cassette B1: Anterior cervix.

Cassette B2: Posterior cervix with mass.

Cassette B3: Mass with relationship to anterior endomyometrium.

Cassettes B4-B5: Mass with relationship to anterior endomyometrium.

Cassette B6: Mass, anterior surface, two sections.

Cassettes B7-B8: Mass with relationship to posterior endomyometrium.

Cassette B9: Mass with relationship to posterior endomyometrium.

Cassette B10: Mass, posterior surface.

Cassette B11: Anterior and posterior endomyometrium.

Cassette B12: Fallopian tube, entire fimbria and cross sections.

Cassette B13: Ovary, bisected.

Cassettes B14-15: Remaining fallopian tube cross sections.

Part C, labeled "sigmoid implant," consists of a single soft to firm, unoriented, pink-tan tissue fragment measuring 1.3 x 0.4 x 0.3 cm in greatest dimension. The specimen is entirely submitted in cassette C1.

Part D, labeled "cul-de-sac nodule," consists of a single, roughly ovoid, firm, white-pink, unoriented tissue fragment measuring 3.5 x 2.4 x 1.2 cm in greatest dimension. The surface of the specimen is inked black. The specimen is serially sectioned perpendicular to the long axis, revealing firm, rubbery, white-pink tissue throughout. Multiple representative sections are submitted in cassettes D1-D2.

Part E, labeled "right common iliac," consists of two soft pink-tan lymph node candidates and a fibrofatty segment containing a portion of vessel. The specimen measures 2 x 1.8 x 0.7 cm in greatest dimension. The fibrofatty segment is carefully examined to reveal no further lymph nodes. The two lymph node candidates are bisected and entirely submitted in cassette E1.

Part F, labeled "right pelvic nodes," consists of multiple small, soft, irregular, unoriented, yellow to red-tan fibrofatty tissue fragments measuring 4.5 x 3 x 0.8 cm in aggregate. The specimen is carefully examined to reveal multiple small, soft, pink-tan lymph node candidates, which are submitted as follows:

Cassettes F1-F2: One lymph node candidate each, bisected.

Cassette F3: Four small lymph node candidates, submitted intact.

Cassette F4: Three small lymph node candidates, submitted intact.

Part G, labeled "left pelvic nodes," consists of multiple soft to firm, yellow to red-tan, unoriented, fibrofatty tissue fragments measuring 4 x 3.8 x 1 cm in aggregate. Careful examination reveals multiple lymph node candidates, some of which are firmer to palpation than normal and are suggestive of possible tumor involvement. The lymph node candidates are submitted as follows:

Cassettes G1-G2: One lymph node candidate, bisected.

Cassette G3: One lymph node candidate, bisected.

Cassettes G4-G5: Multiple small lymph node candidates, submitted intact.

Part H, labeled "pelvic peritoneum biopsy," consists of a single, soft, irregular, unoriented, red-tan fibrous tissue fragment measuring 0.9 x 0.4 x 0.2 cm. The specimen is entirely submitted in cassette H1.

Part I, labeled "bladder biopsy," consists of a single, soft, unoriented, yellow-tan to red-tan fibrofatty

[page 5 of 6]
tissue fragment measuring 1.2 x 0.8 x 0.3 cm. The specimen is entirely submitted in cassette I1. [REDACTED]
Part J, labeled "left pelvic biopsy," consists of a single, roughly ovoid, yellow to red-tan, unoriented, fibrofatty tissue fragment measuring 0.9 x 0.6 x 0.3 cm. The specimen is entirely submitted in cassette J1. [REDACTED]

Part K, labeled "right abdominal biopsy," consists of a single, firm, ovoid, off-white/yellow tissue fragment measuring 0.7 x 0.3 x 0.3 cm. The specimen is entirely submitted in cassette K1. [REDACTED]

Part L, labeled "left abdominal sidewall," consists of a single, soft, irregularly shaped, yellow-tan fibrofatty tissue fragment measuring 0.8 x 0.5 x 0.5 cm. The specimen is entirely submitted in cassette L1. [REDACTED]

Part M, labeled "omentum," consists of a single, irregular sheet of soft, yellow to red-tan fibrofatty tissue measuring 42 x 40 x 1.5 cm and weighing 507 gm. Visual inspection associated with palpation reveals no obvious nodules, implants, or lymph node candidates. The specimen is serially sectioned at regular 1 cm intervals, revealing no interstitial masses. Multiple representative sections are submitted in cassettes M1-M2. [REDACTED]

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]
[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing.

[REDACTED]
Reason: Diagnosis Comment, Addition of
Diagnosis Comment, Addition of [REDACTED]
[REDACTED]

Other Specimens

[REDACTED]

Specimen(s) Received: A: Pelvic Washing, B: Diaphragmatic Washing

Final Diagnosis

A: Pelvic Washing

BENIGN.

Reactive mesothelial cells.

B: Diaphragmatic Washing

BENIGN.

[REDACTED]

[REDACTED]

[page 6 of 6]
[REDACTED]

Specimen(s) Received: Cervical, Thin Prep Imaged

Final Diagnosis

Cervical, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic pattern

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Scant cellularity.

Transformation zone components are present.

[REDACTED]

Source: NCI Genomic Data Commons file fca5eb6f-aa6e-4f03-bedb-96a4fb353de9 (TCGA-09-2044.42D7C4AD-B379-4DC0-BA67-16AA6EAD89D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).